TARGET case TARGET-40-NAAWFB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms.
https://portal.gdc.cancer.gov/cases/c5b94f06-76d5-5bb7-88e8-9102fa613c33

Biospecimens (1 sample)
- Sample TARGET-40-NAAWFB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
